Somatic mutation profile of tumor specimen 0DS4MF from CCDI case PBCHHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (579 days).
Specimen 0DS4MF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c4865aa-7c0a-4ee0-9b4f-ef86a5f41d9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS4ML (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48b6ad1d-d085-4d5f-9734-02cfccfa8ac0

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.1594A>G p.N532D | Missense Mutation (SNP) | VAF 283/676 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV51693446; called by muse, mutect2, varscan2
- ZFHX4 | c.3797C>T p.T1266M | Missense Mutation (SNP) | VAF 82/567 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs763149017, COSV51467227; called by muse, mutect2, varscan2
- KANK3 | c.2317G>T p.A773S | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PLA1A | c.751dup p.A251Gfs*4 | Frame Shift Ins (INS) | VAF 74/216 reads (34%) | called by mutect2, pindel, varscan2
- PTCH1 | c.914_915del p.P305Rfs*13 | Frame Shift Del (DEL) | VAF 369/563 reads (66%) | called by mutect2, pindel, varscan2
- TBX2 | c.1745C>G p.A582G | Missense Mutation (SNP) | VAF 35/567 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ADGRG7 | c.1380-11C>A | Intron (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
